Somatic mutation profile of tumor specimen MP2PRT-PAUJRH-TMP1-A (aliquot MP2PRT-PAUJRH-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUJRH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (778 days).
Specimen MP2PRT-PAUJRH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 691371af-bb4f-4219-9ce2-483194b8ee72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJRH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJRH-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/065a99e2-8aa9-4205-bdbd-11f232e95a58

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 99/232 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARX | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 136/754 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs964935114; called by muse, mutect2, varscan2
- PCDHA2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 170/452 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV65370441; called by muse, mutect2, varscan2
- SCARA3 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 89/366 reads (24%) | catalogued as rs200424172; called by muse, mutect2, varscan2
- SCN3A | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV99325586; called by muse, mutect2, varscan2
- SOCS6 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 110/419 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs748359590; called by muse, mutect2, varscan2
- ASAP3 | c.1087T>A p.F363I | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN5A | c.552C>T p.H184= | Silent (SNP) | VAF 117/363 reads (32%) | catalogued as rs770959082; called by muse, mutect2, varscan2
- UNC13B | c.761+5083G>A | Intron (SNP) | VAF 70/241 reads (29%) | called by muse, mutect2, varscan2
